CCDI case PBCHYC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/26bd8e57-7e77-4a5b-90b2-1e0d71395f61

Demographics
Sex at birth: male.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Occipital lobe; Age at diagnosis: 8.2 years (3,011 days).

Biospecimens (3 samples)
- Sample 0DSEKM: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSEKX: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DSEL6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
